Somatic mutation profile of tumor specimen TCGA-XF-A8HG-01A (aliquot TCGA-XF-A8HG-01A-11D-A364-08) from TCGA case TCGA-XF-A8HG, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 69.6 years (25,421 days).
Specimen TCGA-XF-A8HG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99ec64f7-dec4-4e9e-90c1-46731e29d96e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A8HG-10A (Blood Derived Normal), aliquot TCGA-XF-A8HG-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34764f9c-4912-4856-9f80-4dbf7b7eb0b9

The open-access MAF lists 330 somatic variants for this specimen: 235 protein-altering or splice-affecting, 91 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 199, Silent 91, Nonsense Mutation 17, Frame Shift Del 12, Frame Shift Ins 3, In Frame Del 2, Splice Site 1, Intron 1, 5'UTR 1, Splice Region 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A2 | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553244881, rs796052276, CM113792, COSV63402372; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 37/69 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs754206783, COSV57923527; called by muse, mutect2, varscan2
- ABCB6 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54693223; called by muse, mutect2, varscan2
- ACOT6 | c.364C>G p.Q122E | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as COSV66968798; called by muse, mutect2, varscan2
- ACTL8 | c.653T>C p.L218P | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV64860274; called by muse, mutect2, varscan2
- ADGRE1 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs1183552490, COSV51672382; called by muse, mutect2
- ADGRG2 | c.1504C>T p.H502Y (on ENST00000379869 / NM_001079858.3; = p.H499Y on NM_005756.4) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs757831265, COSV61337664; called by muse, mutect2, varscan2
- AHCYL2 | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs974278005, COSV61485252; called by muse, mutect2, varscan2
- AL645922.1 | c.1025C>G p.A342G | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54959413; called by muse, mutect2, varscan2
- ALOX15 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53396214; called by muse, mutect2, varscan2
- ANK2 | c.5026G>A p.E1676K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.107); catalogued as COSV52146612; called by muse, mutect2, varscan2
- AOAH | c.1021+2_1021+18del p.X341_splice | Splice Site (DEL) | VAF 38/156 reads (24%) | catalogued as COSV51736027; called by mutect2, pindel, varscan2
- ARFGEF3 | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 21/30 reads (70%) | catalogued as COSV52458806, COSV99294584; called by muse, mutect2, varscan2
- ARSA | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1289722910, COSV99332530; called by muse, varscan2
- ASB6 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.769); catalogued as COSV52964424, COSV52965392; called by muse, mutect2, varscan2
- ASB6 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV52964433, COSV99475842; called by muse, mutect2, varscan2
- ASPN | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV65015901; called by muse, mutect2, varscan2
- ATM | c.5290C>A p.L1764I | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as CD991607, COSV53727852, COSV53749370, COSV53751460; called by muse, mutect2, varscan2
- ATP6V0D2 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs149485196, COSV53413236; called by muse, mutect2, varscan2
- ATP9B | c.2603G>A p.R868H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs926575952, COSV56946498; called by muse, mutect2, varscan2
- AUTS2 | c.704G>T p.S235I | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV61384858; called by muse, mutect2, varscan2
- BBS10 | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV67913068; called by muse, mutect2, varscan2
- BICRAL | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58403653; called by muse, mutect2, varscan2
- BRD2 | c.2243A>G p.N748S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); catalogued as COSV66372490; called by muse, mutect2, varscan2
- BRD8 | c.1853T>G p.I618S (on ENST00000254900 / NM_139199.2; = p.I691S on NM_006696.4) | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.718); catalogued as COSV50145358; called by muse, mutect2, varscan2
- C1orf141 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.907); catalogued as rs1424861859, COSV100924411; called by muse, mutect2, varscan2
- C1orf52 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53998087; called by muse, mutect2, varscan2
- C20orf194 | c.2761C>G p.L921V | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV52691829; called by muse, varscan2
- CCDC88A | c.4580T>C p.L1527S (on ENST00000436346 / NM_001365480.1; = p.L1499S on NM_018084.5) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV55056813; called by muse, mutect2, varscan2
- CD247 | c.337G>A p.E113K (on ENST00000362089 / NM_198053.3; = p.E112K on NM_000734.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as COSV62977071; called by muse, mutect2, varscan2
- CDH2 | c.1045A>C p.I349L | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.772); catalogued as COSV52272522; called by muse, mutect2
- CDKN1A | c.19del p.D7Mfs*24 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs1309305537; called by mutect2, pindel, varscan2
- CEP112 | c.1073del p.K358Sfs*6 | Frame Shift Del (DEL) | VAF 23/94 reads (24%) | catalogued as rs769310263; called by mutect2, pindel, varscan2
- CEP63 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV59674572; called by muse, mutect2, varscan2
- CES3 | c.1067G>A p.W356* | Nonsense Mutation (SNP) | VAF 14/14 reads (100%) | catalogued as COSV100310085; called by muse, mutect2, varscan2
- CHTF18 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV50099802; called by muse, mutect2, varscan2
- CLDN9 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 64/71 reads (90%) | SIFT tolerated (0.2); PolyPhen benign (0.142); catalogued as rs765145552, COSV60910140; called by muse, mutect2, varscan2
- CNKSR2 | c.2008G>T p.G670* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99670189; called by muse, mutect2, varscan2
- CNKSR3 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.27); catalogued as rs199640082; called by muse, varscan2
- COL6A3 | c.3337G>C p.E1113Q | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV55080556; called by muse, mutect2, varscan2
- COL7A1 | c.5225C>T p.P1742L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.684); catalogued as COSV60391594; called by muse, mutect2
- COPG1 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 69/136 reads (51%) | catalogued as COSV100136034; called by muse, mutect2, varscan2
- CPNE1 | c.134G>T p.G45V (on ENST00000352393; = p.G50V on NM_003915.5) | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV58289986; called by muse, mutect2, varscan2
- CPSF1 | c.2063C>T p.P688L | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs368943655; called by muse, mutect2
- CSMD3 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs777486805, COSV52108938; called by muse, mutect2
- CST5 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as COSV59013908; called by muse, mutect2, varscan2
- CTIF | c.1522A>G p.R508G | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as COSV56480144; called by muse, mutect2, varscan2
- CTNNA2 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV58136493; called by muse, mutect2, varscan2
- DAG1 | c.778T>C p.W260R | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58182726; called by muse, mutect2, varscan2
- DAPK1 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV63784519; called by muse, mutect2
- DMXL2 | c.352T>C p.W118R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1240906868, COSV51841203; called by muse, mutect2, varscan2
- DNAH8 | c.4454C>G p.S1485* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV59462010; called by muse, mutect2, varscan2
- DOCK8 | c.1508C>G p.S503* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV101210373, COSV66634036; called by muse, mutect2, varscan2
- DOP1B | c.5190G>C p.Q1730H | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV67692231; called by muse, mutect2, varscan2
- DPYSL3 | c.1095C>G p.I365M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV58324238; called by muse, mutect2, varscan2
- DRICH1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV58503237; called by muse, mutect2, varscan2
- DSG4 | c.2732A>G p.Y911C | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV57388563; called by muse, mutect2
- EGR1 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.86); catalogued as COSV53518056; called by muse, mutect2, varscan2
- EMCN | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161432243, COSV56456826, COSV56463657; called by muse, mutect2, varscan2
- ERO1A | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs1397875218, COSV67470708; called by muse, mutect2, varscan2
- EXD3 | c.1966G>T p.G656C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV59803479, COSV59803867; called by muse, mutect2, varscan2
- F11R | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV57036119; called by muse, mutect2, varscan2
- FANCB | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1400003160, COSV60758932; called by muse, mutect2, varscan2
- FASN | c.3050C>T p.S1017L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs373840426; called by muse, mutect2
- FAT2 | c.7414A>G p.T2472A | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.946); catalogued as COSV55814120; called by muse, mutect2, varscan2
- FAT3 | c.3050G>A p.R1017Q | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.625); catalogued as rs376758242; called by muse, mutect2, varscan2
- FEZF1 | c.817T>C p.Y273H | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs757804591, COSV58658241; called by muse, mutect2, varscan2
- FLRT2 | c.1277A>C p.Q426P | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.272); catalogued as COSV58136809; called by muse, mutect2, varscan2
- FLRT3 | c.1436T>C p.M479T | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV53949004; called by muse, mutect2, varscan2
- FRRS1 | c.1339C>A p.P447T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV99790314; called by muse, mutect2
- GAB1 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV53754634; called by muse, mutect2, varscan2
- GFAP | c.881G>A p.C294Y | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1432362877, COSV53649042; called by muse, mutect2, varscan2
- GK2 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 55/91 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV62626200; called by muse, mutect2, varscan2
- GPC2 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV52783920; called by muse, mutect2, varscan2
- HAUS1 | c.740A>G p.N247S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as rs1252258442, COSV56363644, COSV99959615; called by mutect2, varscan2
- HGS | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs757034358, COSV61266712; called by muse, mutect2, varscan2
- HIVEP3 | c.4723G>C p.E1575Q | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as rs145979623; called by muse, varscan2
- HIVEP3 | c.4166G>C p.R1389T | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.366); catalogued as COSV56010133; called by muse, mutect2, varscan2
- HK3 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52837104; called by muse, mutect2, varscan2
- HMCES | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.114); catalogued as COSV59112573; called by muse, mutect2, varscan2
- HNF4A | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as COSV57386205; called by muse, mutect2
- HSPG2 | c.1730T>C p.L577P | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV65969185; called by muse, mutect2, varscan2
- IGF1R | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.144); catalogued as COSV51270855; called by muse, mutect2, varscan2
- IGSF9B | c.2939C>T p.P980L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.574); catalogued as rs766581832, COSV58064110; called by mutect2, varscan2
- IL22RA1 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.965); catalogued as COSV54627628, COSV99582918; called by muse, mutect2, varscan2
- IRAK2 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV56528953; called by muse, mutect2, varscan2
- ITGA1 | c.2228G>A p.R743K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as rs1189557519, COSV50876656; called by muse, mutect2, varscan2
- ITGA2B | c.3111G>C p.E1037D | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs561395069, COSV52231259; called by muse, mutect2, varscan2
- IVL | c.1733T>C p.V578A | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.715); catalogued as rs200641045, COSV64215575; called by muse, mutect2, varscan2
- JPH1 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV60608837; called by muse, mutect2
- KATNAL2 | c.366G>T p.K122N (on ENST00000356157 / NM_001353899.1; = p.K50N on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1280577943, COSV55294051; called by muse, mutect2, varscan2
- KCNA3 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100871329; called by muse, mutect2
- KRT27 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 44/196 reads (22%) | catalogued as COSV100053410; called by muse, mutect2, varscan2
- KRT31 | c.1059C>G p.I353M | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52433504; called by muse, varscan2
- KRT73 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59838000; called by muse, mutect2, varscan2
- LAMA1 | c.4051C>G p.P1351A | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV101056614, COSV67532003, COSV67532535; called by muse, mutect2, varscan2
- LAMB1 | c.676A>T p.N226Y | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV55961878; called by muse, mutect2
- LAMB3 | c.2156G>A p.S719N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1420376405, COSV61915466; called by muse, mutect2, varscan2
- LARS1 | c.2772G>C p.K924N (on ENST00000394434 / NM_020117.11; = p.K897N on NM_016460.3) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV50972382; called by muse, mutect2, varscan2
- LEO1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.04); catalogued as COSV55174779; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 30/117 reads (26%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LPA | c.3120del p.F1040Lfs*5 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as rs753812356; called by mutect2, pindel, varscan2
- LRRC28 | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.899); catalogued as COSV57335777; called by muse, mutect2, varscan2
- LRRC31 | c.1594G>C p.E532Q | Missense Mutation (SNP) | VAF 78/123 reads (63%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV52979648, COSV99246657; called by muse, mutect2, varscan2
- LRRC41 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV58439006; called by muse, mutect2, varscan2
- MACF1 | c.14686del p.T4896Lfs*29 (on ENST00000372915; = p.T2829Lfs*29 on NM_012090.5) | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | catalogued as rs775539898; called by mutect2, pindel, varscan2
- MACF1 | c.16378G>C p.E5460Q (on ENST00000372915; = p.E3393Q on NM_012090.5) | Missense Mutation (SNP) | VAF 33/124 reads (27%) | catalogued as COSV57107708; called by muse, mutect2, varscan2
- MAGEB4 | c.392C>A p.T131K | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV100975142; called by muse, mutect2, varscan2
- MARCHF10 | c.336G>C p.M112I | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV60885345; called by muse, mutect2, varscan2
- MCM2 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV54032148; called by muse, mutect2, varscan2
- MCM4 | c.1380G>C p.E460D | Missense Mutation (SNP) | VAF 212/287 reads (74%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV50621377; called by muse, mutect2, varscan2
- MKI67 | c.1850G>C p.G617A | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.048); catalogued as COSV64072701; called by muse, mutect2, varscan2
- MMS22L | c.1281G>A p.W427* | Nonsense Mutation (SNP) | VAF 23/109 reads (21%) | catalogued as COSV99247893; called by muse, mutect2, varscan2
- MOCS1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV57933601; called by muse, mutect2, varscan2
- MORC2 | c.3064G>A p.A1022T (on ENST00000397641 / NM_001303256.3; = p.A960T on NM_014941.3) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs12330040, COSV53196445; called by muse, mutect2, varscan2
- MTSS1 | c.2033C>A p.P678Q | Missense Mutation (SNP) | VAF 30/293 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV52674304; called by muse, mutect2, varscan2
- MUC4 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 72/122 reads (59%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.316); catalogued as COSV62131694; called by muse, mutect2, varscan2
- MYO1F | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV57792122; called by muse, mutect2, varscan2
- MYO5B | c.2152A>G p.N718D | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV53211890; called by muse, mutect2, varscan2
- NDC80 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV55247005; called by muse, mutect2, varscan2
- NEK1 | c.3365G>A p.G1122D | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1313685718, COSV71454642; called by muse, mutect2, varscan2
- NKAPD1 | c.375T>C p.S125= (on ENST00000280352 / NM_001082970.2; = p.S126= on NM_018195.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 7/29 reads (24%) | catalogued as rs763213755, COSV54777395; called by muse, mutect2, varscan2
- NOG | c.538A>G p.S180G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as COSV60446768; called by muse, varscan2
- NUP42 | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.386); catalogued as rs1295315625, COSV51728774, COSV51730378; called by muse, mutect2, varscan2
- OPLAH | c.2796G>T p.K932N | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV70677144; called by muse, mutect2
- OR2A25 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 45/334 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs374373324, COSV68716883, COSV68717463; called by muse, mutect2, varscan2
- OR5H6 | c.71T>C p.L24S (on ENST00000642105; = p.L8S on NM_001005479.2) | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV67351060, COSV67351313; called by muse, mutect2, varscan2
- OTUD4 | c.1484C>T p.S495L (on ENST00000447906 / NM_001366057.1; = p.S430L on NM_001102653.1) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.288); catalogued as COSV71381485; called by muse, mutect2, varscan2
- PADI3 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1184961546, COSV64934015; called by muse, mutect2, varscan2
- PARD3 | c.2418C>G p.C806W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.571); catalogued as COSV100402253; called by muse, mutect2
- PARD3 | c.1492dup p.A498Gfs*9 | Frame Shift Ins (INS) | VAF 22/118 reads (19%) | catalogued as rs781028175; called by mutect2, pindel, varscan2
- PCDHA13 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV56479774; called by muse, mutect2, varscan2
- PCDHA4 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63539135; called by muse, mutect2, varscan2
- PCDHGA4 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.924); catalogued as COSV53903792; called by muse, mutect2, varscan2
- PCNA | c.533G>C p.G178A | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV52531708; called by muse, mutect2, varscan2
- PDE3A | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV62968565; called by muse, mutect2, varscan2
- PGAP4 | c.472C>A p.L158I | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66387226, COSV66387723; called by muse, varscan2
- PHF14 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV68854259; called by muse, mutect2, varscan2
- PIGU | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54160572; called by muse, varscan2
- PIK3C2B | c.3977G>A p.S1326N | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100916253; called by muse, mutect2
- PIK3CG | c.2554G>C p.E852Q | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV63245761, COSV63254288; called by muse, mutect2, varscan2
- PKHD1 | c.8999T>C p.L3000S | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT tolerated (0.43); PolyPhen benign (0.079); catalogued as COSV61862017; called by muse, mutect2, varscan2
- PKHD1L1 | c.8509G>C p.V2837L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV101007049; called by muse, mutect2
- PLAUR | c.410G>A p.C137Y | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55388666; called by muse, mutect2, varscan2
- PLEKHH3 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs1159062419, COSV52218433; called by muse, mutect2
- PLXNA2 | c.4438G>A p.E1480K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1269275813, COSV65437873; called by muse, mutect2, varscan2
- POLL | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV54573699; called by muse, mutect2, varscan2
- POLR1A | c.4312G>A p.E1438K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.041); catalogued as rs375456606; called by muse, mutect2, varscan2
- POLR1A | c.325A>G p.M109V | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as rs751597666, COSV55689482; called by muse, mutect2, varscan2
- PPFIA3 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1184428081, COSV61949585; called by muse, mutect2, varscan2
- PPP1R26 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1023801657, COSV63354784; called by muse, mutect2, varscan2
- PRICKLE1 | c.1136G>A p.S379N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV61541987; called by mutect2, varscan2
- PSMA4 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV50384455; called by muse, mutect2, varscan2
- PSORS1C1 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.224); catalogued as COSV52535106; called by muse, mutect2, varscan2
- PTGER2 | c.315G>C p.E105D | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55418184, COSV99817402; called by muse, mutect2, varscan2
- PTPN22 | c.1787T>C p.L596S (on ENST00000359785 / NM_001193431.2; = p.L541S on NM_012411.5) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV63084367; called by muse, mutect2, varscan2
- PUM1 | c.2860G>T p.V954F | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1364996436, COSV57081991; called by muse, mutect2, varscan2
- PXMP4 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 106/120 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54132697; called by muse, mutect2, varscan2
- RAD51 | c.697T>G p.S233A | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV51111041; called by mutect2, varscan2
- RAPGEF2 | c.2037A>G p.I679M | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52425054; called by muse, mutect2, varscan2
- RAPGEF5 | c.1591G>C p.V531L (on ENST00000401957 / NM_001367602.2; = p.V834L on NM_012294.5) | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs1018724572, COSV59779173; called by muse, mutect2, varscan2
- RETREG1 | c.1323dup p.I442Hfs*9 (on ENST00000306320 / NM_001034850.2; = p.I301Hfs*9 on NM_019000.4) | Frame Shift Ins (INS) | VAF 6/53 reads (11%) | catalogued as rs1294300253; called by mutect2, pindel, varscan2
- REV1 | c.1843C>T p.L615F | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51482012; called by muse, mutect2, varscan2
- RMDN1 | c.16C>G p.R6G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.131); catalogued as rs1026914855, COSV52203516, COSV52204039; called by muse, mutect2
- RPA3 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 93/215 reads (43%) | catalogued as rs1331860433, COSV99778833; called by muse, mutect2, varscan2
- RPL6 | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.072); catalogued as COSV52516504, COSV52516854; called by muse, mutect2, varscan2
- RPS6 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as rs1340510897, COSV59547544; called by muse, mutect2, varscan2
- RPS6KA5 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs1315968352, COSV56219661; called by muse, mutect2, varscan2
- SASH1 | c.3665T>C p.I1222T | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV100821529; called by muse, mutect2
- SCN4A | c.3100G>C p.E1034Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV71125699; called by muse, mutect2
- SDHC | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 83/240 reads (35%) | catalogued as COSV100713798; called by muse, mutect2, varscan2
- SDK1 | c.2177C>A p.T726K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.351); catalogued as COSV67357537; called by muse, mutect2, varscan2
- SGK2 | c.622G>C p.G208R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58312191; called by muse, mutect2, varscan2
- SGO1 | c.1159A>G p.K387E | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV55422892; called by muse, mutect2
- SH3PXD2A | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs1211083764, COSV60115792; called by muse, mutect2, varscan2
- SIX5 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1221627931, COSV52175669; called by muse, mutect2, varscan2
- SLC16A9 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV68098327; called by muse, mutect2, varscan2
- SLC29A1 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.202); catalogued as COSV57577383; called by muse, mutect2, varscan2
- SLC39A3 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.727); catalogued as rs779306867, COSV54117417; called by muse, mutect2, varscan2
- SLC8B1 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52526387; called by muse, mutect2, varscan2
- SORCS3 | c.1325A>T p.D442V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV63803295; called by muse, mutect2, varscan2
- SPATA45 | c.257G>C p.R86T | Missense Mutation (SNP) | VAF 75/133 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV60571415; called by muse, mutect2, varscan2
- SPATA7 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1383336971, COSV50416004; called by muse, mutect2, varscan2
- SPEG | c.7886C>T p.S2629L | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.684); catalogued as COSV56663675; called by muse, mutect2, varscan2
- SPRTN | c.869C>G p.S290* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as COSV50478283, COSV99150189; called by muse, mutect2, varscan2
- SPSB2 | c.384C>G p.S128R | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV51289999; called by muse, mutect2, varscan2
- SRBD1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 80/118 reads (68%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1353374303, COSV55396078; called by muse, mutect2, varscan2
- SREBF2 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.059); catalogued as rs755835024, COSV63330526; called by muse, mutect2, varscan2
- STIL | c.224del p.N75Ifs*10 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | catalogued as rs769117150; called by mutect2, varscan2
- STRA8 | c.263A>G p.Q88R (on ENST00000275764; = p.Q66R on NM_182489.2) | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV51960518; called by muse, mutect2
- SYNE1 | c.23560G>A p.E7854K (on ENST00000367255 / NM_182961.4; = p.E7783K on NM_033071.3) | Missense Mutation (SNP) | VAF 118/196 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54914060; called by muse, mutect2, varscan2
- SYNPO2L | c.1270C>G p.R424G (on ENST00000394810 / NM_001114133.3; = p.R200G on NM_024875.5) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.148); catalogued as rs139351387, COSV100866489; called by muse, varscan2
- SYTL4 | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV52165603; called by muse, mutect2, varscan2
- TANC2 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.909); catalogued as rs774928576, COSV67330523; called by muse, mutect2, varscan2
- TAS2R14 | c.906C>G p.F302L | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV67852623, COSV67859114; called by muse, mutect2, varscan2
- TDRD1 | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs369155631; called by muse, varscan2
- TEKT4 | c.144C>G p.C48W | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.677); catalogued as COSV54623064; called by muse, mutect2, varscan2
- TEX2 | c.2047C>T p.R683* | Nonsense Mutation (SNP) | VAF 58/197 reads (29%) | catalogued as rs758281484, COSV99366667, COSV99367608; called by muse, mutect2, varscan2
- TEX26 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 48/130 reads (37%) | catalogued as rs201472831, COSV100994182; called by muse, mutect2, varscan2
- TEX33 | c.503T>C p.I168T (on ENST00000381821 / NM_001163857.2; = p.I83T on NM_178552.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.675); catalogued as rs761769127, COSV67821281; called by muse, mutect2, varscan2
- TLN1 | c.6598G>A p.D2200N | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV59204393; called by muse, mutect2, varscan2
- TMEM200A | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1042646760, COSV51649569, COSV99759006; called by muse, mutect2, varscan2
- TMEM89 | c.228_230del p.T77del | In Frame Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs1559461179; called by pindel, varscan2
- TNC | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776411890, COSV60780931; called by muse, mutect2, varscan2
- TTN | c.50995G>T p.E16999* (on ENST00000591111; = p.E9575* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as COSV100634774; called by muse, mutect2, varscan2
- UBQLN3 | c.832T>G p.F278V | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV61163272; called by muse, varscan2
- UBR4 | c.4553T>C p.L1518P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64383208; called by muse, mutect2
- UGT2B10 | c.1460A>C p.Y487S | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55318876; called by muse, mutect2, varscan2
- USP16 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV57624072; called by muse, mutect2
- VPS13C | c.8535C>A p.N2845K (on ENST00000644861 / NM_020821.3; = p.N2802K on NM_017684.5) | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51123784; called by muse, mutect2, varscan2
- VSNL1 | c.492C>G p.D164E | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV54597639; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | catalogued as rs746919573; called by mutect2, varscan2
- WNT16 | c.976G>T p.G326C (on ENST00000222462 / NM_057168.2; = p.G316C on NM_016087.2) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539923811, COSV55974918; called by muse, mutect2, varscan2
- WWOX | c.724C>T p.L242F | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs759826716, COSV68344456; called by muse, mutect2
- XKR7 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs748529332, COSV73812898; called by muse, mutect2, varscan2
- YLPM1 | c.2673G>C p.K891N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV53106788; called by muse, mutect2, varscan2
- YLPM1 | c.2796G>C p.E932D | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV53106809; called by muse, mutect2, varscan2
- ZBTB45 | c.1472G>A p.C491Y | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99564680; called by muse, mutect2
- ZIC4 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV67170757, COSV67173628; called by muse, mutect2, varscan2
- ZNF236 | c.3585C>G p.Y1195* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV99471468; called by muse, mutect2, varscan2
- ZNF35 | c.1497G>C p.E499D | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56075922; called by muse, mutect2, varscan2
- ZNF518B | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58721469, COSV58723095; called by muse, mutect2, varscan2
- ZNF587 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100299724; called by mutect2, varscan2
- ZNF626 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 46/114 reads (40%) | catalogued as rs1555769482, COSV101657019; called by muse, mutect2, varscan2
- ZNF681 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV68073550; called by muse, mutect2, varscan2
- ZNF714 | c.557C>G p.S186* | Nonsense Mutation (SNP) | VAF 33/106 reads (31%) | catalogued as COSV99395691; called by muse, mutect2, varscan2
- ZPR1 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57062367; called by muse, mutect2, varscan2
- ASAH1 | c.384dup p.E129* | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by pindel, varscan2
- COG7 | c.288del p.K96Nfs*14 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- GPD1L | c.893del p.K298Sfs*102 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | called by mutect2, pindel, varscan2
- PTPN13 | c.4520del p.N1507Ifs*5 (on ENST00000411767 / NM_080683.3; = p.N1488Ifs*5 on NM_006264.3) | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, varscan2
- SCEL | c.1056_1069del p.N352Kfs*6 (on ENST00000349847 / NM_144777.3; = p.N332Kfs*6 on NM_003843.4) | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- TPCN2 | c.1851_1863delinsT p.N618_A621del | In Frame Del (DEL) | VAF 14/67 reads (21%) | called by pindel, varscan2*
- ZPBP2 | c.848del p.G283Efs*28 (on ENST00000348931 / NM_199321.3; = p.G261Efs*28 on NM_198844.3) | Frame Shift Del (DEL) | VAF 27/118 reads (23%) | called by mutect2, pindel, varscan2
- ADAMTS3 | c.1152G>A p.L384= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as COSV54385664; called by muse, mutect2, varscan2
- ALKAL1 | c.366G>C p.V122= | Silent (SNP) | VAF 58/85 reads (68%) | catalogued as COSV62129913; called by muse, mutect2, varscan2
- AMBN | c.162G>A p.Q54= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs1297792011, COSV59825278; called by muse, mutect2, varscan2
- ANP32D | c.381C>T p.N127= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs1341746641, COSV56980132; called by muse, mutect2, varscan2
- ARHGAP32 | c.3849T>C p.A1283= (on ENST00000310343 / NM_001378025.1; = p.A934= on NM_014715.4) | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV59843653; called by muse, mutect2, varscan2
- ARHGEF2 | c.570C>T p.L190= (on ENST00000361247 / NM_001162383.2; = p.L163= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV58106910; called by muse, mutect2, varscan2
- ATXN7L2 | c.1791C>T p.G597= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV60203958; called by muse, mutect2, varscan2
- B3GALT5 | c.483C>T p.I161= | Silent (SNP) | VAF 48/68 reads (71%) | catalogued as COSV58197981; called by muse, mutect2, varscan2
- BANK1 | c.459C>A p.I153= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV59838693; called by muse, mutect2, varscan2
- BARHL1 | c.543G>A p.A181= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV55038115; called by muse, mutect2, varscan2
- BBS12 | c.2082T>C p.H694= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs1560709109, COSV58561422; called by muse, mutect2, varscan2
- BRINP3 | c.1143G>A p.K381= | Silent (SNP) | VAF 27/161 reads (17%) | catalogued as rs375701759; called by muse, mutect2, varscan2
- CAMLG | c.381C>T p.V127= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV51804321; called by muse, mutect2, varscan2
- CD6 | c.939G>A p.E313= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as rs371204521; called by muse, mutect2, varscan2
- CES2 | c.1506C>T p.G502= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs771779336, COSV57696270; called by muse, mutect2, varscan2
- CGN | c.1398G>A p.L466= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1281284532, COSV54968258; called by muse, mutect2, varscan2
- CNTN6 | c.28C>T p.L10= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as COSV63162882; called by muse, mutect2, varscan2
- CPNE6 | c.1617C>T p.I539= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV53742611; called by muse, mutect2, varscan2
- CST5 | c.174C>T p.V58= | Silent (SNP) | VAF 62/274 reads (23%) | catalogued as COSV59013918; called by muse, varscan2
- CUL9 | c.5004G>A p.K1668= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV99336188; called by muse, mutect2, varscan2
- DACT3 | c.1830G>A p.A610= | Silent (SNP) | VAF 69/387 reads (18%) | catalogued as COSV56258404; called by muse, mutect2, varscan2
- DIDO1 | c.2328A>G p.R776= | Silent (SNP) | VAF 54/273 reads (20%) | catalogued as COSV56614493; called by muse, mutect2, varscan2
- DLEC1 | c.3502C>A p.R1168= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs748835586, COSV57295567; called by muse, varscan2
- DOP1B | c.606C>T p.F202= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs747714952, COSV67692230; called by muse, mutect2, varscan2
- DYRK1A | c.1989T>G p.T663= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV58703893; called by muse, mutect2, varscan2
- EDRF1 | c.150A>G p.R50= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV61762516; called by muse, mutect2, varscan2
- ESR1 | c.1215T>C p.A405= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs1317463397, COSV52782729; called by muse, mutect2, varscan2
- GAD2 | c.1029A>C p.A343= | Silent (SNP) | VAF 45/190 reads (24%) | catalogued as COSV52150980; called by muse, mutect2, varscan2
- GIGYF1 | c.1407C>T p.L469= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs753660933, COSV51939456; called by muse, mutect2, varscan2
- GPRASP1 | c.3903G>A p.L1301= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV64354865; called by muse, mutect2, varscan2
- HIP1 | c.807G>A p.L269= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as COSV61183445; called by muse, mutect2, varscan2
- HIVEP3 | c.4638G>A p.L1546= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV56010127; called by muse, varscan2
- HS3ST5 | c.453C>A p.I151= | Silent (SNP) | VAF 86/157 reads (55%) | catalogued as COSV57134938, COSV57142254; called by muse, mutect2
- IRX6 | c.75A>G p.T25= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV51859227; called by muse, mutect2, varscan2
- KCNH4 | c.2322C>A p.S774= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99238034; called by muse, mutect2
- KISS1R | c.216G>A p.P72= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs780363542, COSV99311949; called by muse, varscan2
- KLHL17 | c.1857G>A p.V619= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV58530913; called by muse, mutect2
- KRT3 | c.183C>T p.G61= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs368081511, COSV58816485; called by muse, mutect2, varscan2
- KRT31 | c.1017C>T p.Y339= | Silent (SNP) | VAF 33/172 reads (19%) | catalogued as rs371841210; called by muse, varscan2
- LHFPL1 | c.558C>T p.L186= | Silent (SNP) | VAF 27/31 reads (87%) | catalogued as rs767865984, COSV64332962; called by muse, mutect2, varscan2
- LPAR3 | c.969C>A p.I323= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV65452749; called by muse, mutect2, varscan2
- MAGEC1 | c.2590T>C p.L864= | Silent (SNP) | VAF 52/108 reads (48%) | catalogued as COSV53568385; called by muse, mutect2, varscan2
- MARCHF10 | c.2124G>A p.V708= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV60885342; called by muse, mutect2, varscan2
- MDC1 | c.2343A>G p.P781= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV64523400; called by muse, mutect2
- MKRN3 | c.603G>A p.A201= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs1000780930, COSV58808679; called by muse, mutect2, varscan2
- MRE11 | c.891T>C p.H297= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV60574129; called by muse, mutect2, varscan2
- MTHFR | c.246G>A p.R82= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV56738071; called by muse, mutect2, varscan2
- MYH14 | c.2196C>T p.F732= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs1310060198, COSV51832459; called by muse, mutect2, varscan2
- MYH2 | c.3648G>A p.L1216= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs768382253, COSV55432148, COSV55444603; called by muse, mutect2, varscan2
- NFE2L1 | c.522G>A p.L174= | Silent (SNP) | VAF 206/723 reads (28%) | catalogued as rs1567754028, COSV62582806; called by muse, mutect2, varscan2
- OPRK1 | c.921T>C p.A307= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV55568487; called by muse, mutect2
- OR2S2 | c.934C>T p.L312= | Silent (SNP) | VAF 4/97 reads (4%) | called by muse, mutect2
- OR51B6 | c.219G>A p.L73= | Silent (SNP) | VAF 62/105 reads (59%) | catalogued as COSV66512282; called by muse, mutect2, varscan2
- PAM | c.2394T>C p.A798= | Silent (SNP) | VAF 22/163 reads (13%) | catalogued as COSV57209710; called by muse, mutect2, varscan2
- PIGU | c.1086C>T p.I362= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs1443455445, COSV54160593; called by muse, varscan2
- PIH1D1 | c.6G>A p.A2= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs1349143553, COSV51806382; called by muse, mutect2, varscan2
- PLEKHM1 | c.114G>A p.T38= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs201391140, COSV69598550; called by muse, mutect2, varscan2
- PYGO2 | c.1149C>T p.L383= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs1292429094, COSV63756635; called by muse, mutect2, varscan2
- RAB3GAP2 | c.4002A>G p.T1334= | Silent (SNP) | VAF 40/196 reads (20%) | catalogued as rs1371815451, COSV56957744; called by muse, mutect2, varscan2
- RBBP6 | c.471A>G p.P157= | Silent (SNP) | VAF 40/44 reads (91%) | catalogued as COSV60503405; called by muse, mutect2, varscan2
- RC3H1 | c.2919G>A p.L973= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as COSV51197958; called by muse, mutect2, varscan2
- RESF1 | c.4305G>A p.A1435= | Silent (SNP) | VAF 42/69 reads (61%) | catalogued as rs1465064997, COSV57019855, COSV57020949; called by muse, mutect2, varscan2
- RIBC1 | c.186G>A p.K62= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV51447496; called by muse, mutect2, varscan2
- RRP1 | c.267G>A p.T89= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as rs762124046, COSV71856759; called by muse, mutect2, varscan2
- SCRN2 | c.291C>T p.N97= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs374764950, COSV51635007; called by muse, mutect2
- SLC18A2 | c.321G>A p.V107= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV53688613; called by muse, mutect2, varscan2
- SLC35A4 | c.627C>T p.L209= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV60051549; called by muse, mutect2, varscan2
- SNCAIP | c.2334T>C p.P778= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV54402781; called by muse, mutect2, varscan2
- SPEG | c.7770C>G p.L2590= | Silent (SNP) | VAF 28/38 reads (74%) | catalogued as COSV56663668; called by muse, mutect2, varscan2
- STAR | c.399C>G p.L133= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV52416928; called by muse, mutect2, varscan2
- SUCO | c.2877G>C p.V959= | Silent (SNP) | VAF 77/147 reads (52%) | catalogued as COSV55262234, COSV55267305; called by muse, mutect2, varscan2
- TAPBP | c.399C>A p.L133= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV69666976; called by muse, mutect2, varscan2
- TCERG1 | c.1500G>A p.K500= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs768355420, COSV57034043; called by muse, mutect2, varscan2
- TIMM50 | c.450C>T p.L150= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs373729518; called by muse, mutect2
- TMEM130 | c.1290C>G p.V430= (on ENST00000416379 / NM_001134450.2; = p.V418= on NM_152913.3) | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV59557933; called by muse, mutect2, varscan2
- TMEM135 | c.315C>T p.A105= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs764290159, COSV59696646; called by muse, mutect2, varscan2
- TOP1 | c.2122C>A p.R708= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV63692956, COSV63693268; called by muse, mutect2
- TSPAN31 | c.405C>G p.L135= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as COSV57275673; called by muse, mutect2, varscan2
- TTN | c.97656C>A p.I32552= (on ENST00000591111; = p.I25128= on NM_003319.4) | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as rs1317954218, COSV59902068; called by muse, mutect2, varscan2
- USP19 | c.3066C>G p.V1022= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as COSV60045014; called by muse, mutect2, varscan2
- UTS2R | c.318C>T p.F106= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100493420; called by muse, mutect2
- VCAN | c.9111T>C p.I3037= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV54097628; called by muse, mutect2
- VPS13A | c.1431T>C p.V477= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV100653788; called by muse, mutect2
- VPS51 | c.1638T>C p.T546= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs1227347022, COSV54206131; called by muse, mutect2, varscan2
- WDR33 | c.3972G>A p.P1324= | Silent (SNP) | VAF 11/125 reads (9%) | catalogued as rs144447847; called by muse, mutect2
- XYLT2 | c.1773C>T p.S591= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs769862588, COSV50016775; called by muse, mutect2, varscan2
- ZNF34 | c.546C>T p.L182= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV58638329; called by muse, mutect2, varscan2
- ZNF43 | c.1944A>G p.K648= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs1334848833, COSV61682845, COSV61684431; called by muse, mutect2, varscan2
- ZNF592 | c.1374G>C p.S458= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV55435216; called by muse, mutect2, varscan2
- ZNF610 | c.720C>T p.V240= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV58343682; called by muse, mutect2, varscan2
- ZNF91 | c.678T>C p.T226= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as COSV56080838; called by muse, mutect2, varscan2
- AC024940.1 | n.3254C>T | RNA (SNP) | VAF 37/59 reads (63%) | catalogued as rs367816813; called by muse, mutect2, varscan2
- RGS3 | c.3081-379T>C | Intron (SNP) | VAF 8/116 reads (7%) | catalogued as rs139001882, COSV59516932; called by muse, mutect2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 10/17 reads (59%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TMEM132E | chr17:34579022 G>A | 5'Flank (SNP) | VAF 15/151 reads (10%) | catalogued as rs1293502600; called by muse, mutect2, varscan2
